Gene-level copy-number profile of tumor specimen TCGA-B6-A409-01A from TCGA case TCGA-B6-A409, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 44.3 years (16,178 days).
Specimen TCGA-B6-A409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.97bcb0a5-f1c7-4277-bce3-763473b3ff4f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A409-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13f9da01-41e1-495d-ab87-99348777616c

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 39,471; copy number 2: 14,219; copy number 3: 4,768; copy number 4: 1,225; copy number 5: 89; copy number 7: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A409-01A-11D-A242-01): tumor purity 0.25, ploidy 6.08, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–10,796,650, 1 gene (within-gene range 0–1): CASZ1.
- chr12:125,808,668–126,912,322, 29 genes: AC005252.2, AC005252.4, AC005252.3, AC005252.1, LINC00939, LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1, NDUFA5P6, AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 6,094 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,306,368–69,435,409, 789 genes, copy number 3–5 (broad region; genes not listed).
- chr1:69,919,322–70,786,468, 16 genes, copy number 3 (within-gene range 2–3): PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5, CASP3P1, LINC01788, AL513285.1.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 3–5 (broad region; genes not listed).
- chr6:164,791,288–165,309,605, 5 genes, copy number 3: AL450345.2, AL450345.1, AL133538.1, AL136100.1, C6orf118.
- chr6:165,409,562–165,409,676, 1 gene, copy number 3: RNA5SP226.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 3 (broad region; genes not listed).
- chr10:42,185,339–65,055,003, 355 genes, copy number 3 (broad region; genes not listed).
- chr16:34,139,189–55,706,192, 308 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr20:46,894,624–54,859,812, 154 genes, copy number 4–7 (broad region; genes not listed).
- chr21:35,887,195–46,665,124, 328 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 37,185. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
